Somatic mutation profile of tumor specimen TCGA-TQ-A7RJ-01A (aliquot TCGA-TQ-A7RJ-01A-11D-A33T-08) from TCGA case TCGA-TQ-A7RJ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 25.2 years (9,209 days).
Specimen TCGA-TQ-A7RJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72db560c-56ec-4d51-a0eb-669569903aa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RJ-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RJ-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98f04eb5-936e-467d-9f3c-7d5098c9fb71

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 27, Silent 12, Nonsense Mutation 3, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 78/209 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 66/179 reads (37%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.4121-1G>C p.X1374_splice | Splice Site (SNP) | VAF 36/124 reads (29%) | catalogued as COSV100969887; called by muse, varscan2
- ATRX | c.2165C>G p.S722* | Nonsense Mutation (SNP) | VAF 34/924 reads (4%) | catalogued as COSV100969889; called by muse, mutect2
- BAK1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1051911; called by muse, mutect2, varscan2
- CCDC39 | c.896A>G p.D299G | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV99866847; called by muse, mutect2
- CUL2 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs369928960; called by muse, mutect2, varscan2
- DCAF12L2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV63580780; called by muse, mutect2
- FLI1 | c.429G>C p.E143D | Missense Mutation (SNP) | VAF 17/415 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99857316; called by muse, mutect2
- FMN1 | c.3892C>G p.P1298A (on ENST00000616417 / NM_001277313.2; = p.P1075A on NM_001103184.4) | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs575817325, COSV100567827; called by muse, mutect2, varscan2
- GOLPH3 | c.597G>C p.M199I | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV99416940; called by muse, mutect2
- H3C2 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV52517730, COSV52518686, COSV99451691; called by muse, mutect2
- ITGA10 | c.1409C>G p.A470G | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100994649, COSV100995059; called by muse, mutect2
- KCNMA1 | c.3209C>T p.P1070L (on ENST00000286628 / NM_001161352.2; = p.P1012L on NM_002247.4) | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1364516204, COSV99694421; called by muse, mutect2, varscan2
- KLHL34 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.297); catalogued as COSV65278967; called by muse, mutect2, varscan2
- MSH5 | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV100994635, COSV100994797; called by muse, mutect2
- MUC16 | c.12404C>T p.T4135I | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.207); catalogued as rs1195825856, COSV101197740, COSV101199522; called by muse, mutect2, varscan2
- OR4P4 | c.13A>C p.N5H | Missense Mutation (SNP) | VAF 158/391 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); catalogued as COSV100111515; called by muse, mutect2, varscan2
- PHACTR1 | c.1436A>G p.N479S | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100275130; called by muse, mutect2
- PLD5 | c.1544A>T p.K515I (on ENST00000442594; = p.K453I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/557 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.062); catalogued as COSV100138524; called by muse, mutect2
- RASGRP4 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as rs766578361, COSV99498370; called by muse, mutect2, varscan2
- SERPINC1 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs374205395, CD961789; called by muse, mutect2
- SFMBT2 | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs375469710; called by mutect2, varscan2
- SIRT3 | c.152G>C p.R51T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1445098247, COSV100728699; called by muse, mutect2, varscan2
- SLC24A3 | c.1472C>G p.S491C | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100038945; called by muse, mutect2
- SLIT1 | c.3357G>C p.E1119D | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99820443; called by muse, mutect2, varscan2
- SZT2 | c.10192C>G p.Q3398E (on ENST00000634258 / NM_001365999.1; = p.Q3341E on NM_015284.4) | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100981176, COSV65095043; called by muse, mutect2, varscan2
- TP53 | c.359del p.K120Sfs*3 | Frame Shift Del (DEL) | VAF 71/183 reads (39%) | catalogued as COSV52809633, COSV52992572, COSV53213865; called by mutect2, pindel, varscan2
- UTRN | c.7222G>C p.D2408H | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100839428; called by muse, mutect2
- XIAP | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 53/319 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.622); catalogued as COSV100848807; called by muse, mutect2, varscan2
- ZMYM2 | c.3226G>A p.V1076I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs542204363, COSV101243459; called by muse, mutect2, varscan2
- POLR2A | c.4528A>T p.M1510L | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AGRN | c.1638C>T p.C546= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as rs142440782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIRC3 | c.1494G>A p.T498= | Silent (SNP) | VAF 20/356 reads (6%) | catalogued as rs1200132182, COSV54816612; called by muse, mutect2
- BPTF | c.2925A>G p.L975= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as COSV100073823; called by muse, mutect2
- DGKK | c.1467A>G p.S489= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV101052863; called by muse, mutect2, varscan2
- DNMT3A | c.1758C>T p.C586= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs746498722, COSV53071030; called by muse, mutect2, varscan2
- ERO1A | c.1173T>C p.C391= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as COSV101193561; called by muse, mutect2
- GPR101 | c.339G>C p.L113= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV99981212; called by muse, mutect2
- GTF2F1 | c.99A>G p.A33= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV101080987; called by muse, mutect2, varscan2
- KCTD21 | c.435C>T p.N145= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as rs766255208, COSV60741122; called by muse, mutect2
- MSH5 | c.1185C>T p.V395= | Silent (SNP) | VAF 10/151 reads (7%) | catalogued as COSV100994634; called by muse, mutect2
- PAGR1 | c.108C>T p.T36= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100232557; called by muse, mutect2, varscan2
- PTPRM | c.3093A>G p.L1031= | Silent (SNP) | VAF 7/157 reads (4%) | catalogued as COSV100154340; called by muse, mutect2
